Somatic mutation profile of tumor specimen 0DPJT8 from CCDI case PBCDSX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Mandible; Age at diagnosis: 5.4 years (1,977 days).
Specimen 0DPJT8: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1f701aa-d41b-471e-a407-da33f8cf0d50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJSC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/029722b6-d8ec-465e-8b63-17f4554dcddb

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Intron 3, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DBP | c.950G>C p.R317P | Missense Mutation (SNP) | VAF 79/345 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV99709213; called by muse, mutect2, varscan2
- FNTA | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 40/1157 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs777046833, COSV100172504; called by muse, mutect2
- HFE | c.286C>G p.H96D | Missense Mutation (SNP) | VAF 268/786 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV58512886; called by muse, mutect2, varscan2
- IDO2 | c.482G>A p.G161E (on ENST00000389060; = p.G174E on NM_194294.2) | Missense Mutation (SNP) | VAF 438/1883 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58423419; called by muse, mutect2, varscan2
- MIA2 | c.1277A>T p.E426V | Missense Mutation (SNP) | VAF 155/454 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs537063219; called by muse, mutect2, varscan2
- PKP4 | c.2688G>T p.L896F | Missense Mutation (SNP) | VAF 297/552 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61580743; called by muse, mutect2, varscan2
- RGS9 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 133/535 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.039); catalogued as COSV52225580; called by muse, mutect2, varscan2
- ANKLE1 | c.968C>G p.A323G (on ENST00000394458; = p.A269G on NM_152363.6) | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2
- ENTPD6 | c.158_159insA p.F54Vfs*54 | Frame Shift Ins (INS) | VAF 66/368 reads (18%) | called by mutect2, pindel*, varscan2
- EPHA6 | c.2784+2T>A p.X928_splice (on ENST00000389672 / NM_001080448.3; = p.X320_splice on NM_173655.4) | Splice Site (SNP) | VAF 74/294 reads (25%) | called by muse, mutect2, varscan2
- HEATR3 | c.1150T>C p.W384R | Missense Mutation (SNP) | VAF 148/375 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.6153G>A p.W2051* | Nonsense Mutation (SNP) | VAF 95/396 reads (24%) | called by muse, mutect2, varscan2
- POLR2A | c.981+1G>A p.X327_splice | Splice Site (SNP) | VAF 14/374 reads (4%) | called by muse, mutect2
- POM121L2 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 99/769 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RIPOR3 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SELP | c.2086A>G p.T696A | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2
- ZNF814 | c.1967C>G p.T656R | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2
- ANKRD34B | c.366T>C p.L122= | Silent (SNP) | VAF 259/325 reads (80%) | called by muse, mutect2, varscan2
- BHLHE22 | c.111C>T p.S37= | Silent (SNP) | VAF 44/781 reads (6%) | called by muse, mutect2
- H3C3 | c.12G>A p.T4= | Silent (SNP) | VAF 126/301 reads (42%) | catalogued as rs770888546, COSV63550993; called by muse, mutect2, varscan2
- HFE | c.345C>A p.S115= | Silent (SNP) | VAF 318/894 reads (36%) | catalogued as COSV100352731, COSV58513751; called by muse, mutect2, varscan2
- HIBCH | c.249G>A p.L83= | Silent (SNP) | VAF 89/289 reads (31%) | catalogued as rs762157218; called by muse, mutect2, varscan2
- MED28 | c.438C>T p.I146= | Silent (SNP) | VAF 285/740 reads (39%) | called by muse, mutect2, varscan2
- RNF212 | c.384A>G p.T128= | Silent (SNP) | VAF 79/417 reads (19%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3612G>A p.K1204= | Silent (SNP) | VAF 93/427 reads (22%) | called by muse, mutect2, varscan2
- BIN1 | c.1264-92G>A | Intron (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- DST | c.4296+3952A>C | Intron (SNP) | VAF 72/1510 reads (5%) | called by muse, mutect2
- ITGA5 | c.1417+63C>G | Intron (SNP) | VAF 206/473 reads (44%) | called by muse, mutect2, varscan2
